FM case AD15557 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/3e154f2b-afa8-4ce6-a32e-8d2a48bd20b4

Female, 66.7 years: Acinar cell tumor (ICD-O-3 8550/1) of the major salivary gland; specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 23% (pathologist estimate recorded by GDC). Sample type: Tumor.
